Gene-level copy-number profile of tumor specimen TCGA-06-0209-01A from TCGA case TCGA-06-0209, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.3 years (27,877 days).
Specimen TCGA-06-0209-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.b6135ba2-af1f-4da4-aa55-577f1c9f8da4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0209-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ff8c1ab-0f31-4541-8bf3-c19ef6e0b528

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,273; copy number 2: 40,638; copy number 3: 11,713; copy number 4: 89; copy number 6: 9; copy number 7: 4; copy number 31: 10; copy number 42: 11; copy number 43: 26; copy number 44: 43; copy number 46: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-0209-01): tumor purity 1, ploidy 4.04, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 106 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:67,040,546–67,397,980, 4 genes, copy number 7 (within-gene range 2–7): AC007403.1, LINC01828, LINC01829, AC023115.1.
- chr2:120,542,905–121,182,580, 9 genes, copy number 6: AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1.
- chr3:190,305,707–190,892,429, 11 genes, copy number 42: CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC.
- chr7:54,330,670–55,955,239, 43 genes, copy number 44 (within-gene range 3–44): LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713.
- chr12:19,445,949–19,509,245, 3 genes, copy number 46: RNU6-254P, EEF1A1P4, AC091805.1.
- chr12:57,723,761–57,797,554, 10 genes, copy number 31 (within-gene range 2–31): AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3.
- chr12:68,674,371–69,579,793, 26 genes, copy number 43 (within-gene range 2–43): AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2.

Autosomal genes at a single copy (total copy number 1): 4,909. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
